Somatic mutation profile of tumor specimen C3L-06435-01 (aliquot CPT0373330006) from CPTAC case C3L-06435, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 63.2 years (23,073 days).
Specimen C3L-06435-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Foot; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce092bfd-49b1-4999-a90c-21fe4982cedd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06435-31 (Blood Derived Normal), aliquot CPT0374570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f77adaf1-dd75-4bb4-84de-32ada849fbce

The open-access MAF lists 54 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 42, Silent 11, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 70/356 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 116/363 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587784409, CM071102, COSV59127821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLEC2L | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.684); catalogued as COSV101406068; called by muse, mutect2, varscan2
- CSMD1 | c.7508G>A p.G2503E (on ENST00000520002; = p.G2502E on NM_033225.6) | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.999); catalogued as COSV59310410; called by muse, mutect2, varscan2
- CTAGE1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs377367059; called by muse, mutect2, varscan2
- CYP4F22 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1447106813; called by muse, mutect2, varscan2
- DMBT1 | c.446T>C p.M149T | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1333784572; called by muse, mutect2, varscan2
- DPP6 | c.962C>T p.S321F (on ENST00000377770 / NM_001364500.2; = p.S259F on NM_001936.5) | Missense Mutation (SNP) | VAF 94/354 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100128427; called by muse, mutect2, varscan2
- FPR3 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 92/456 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59331110; called by muse, mutect2, varscan2
- IRAK2 | c.809T>C p.L270S | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747827219; called by muse, mutect2, varscan2
- KRTAP10-8 | c.725C>A p.P242Q | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as COSV100554880, COSV58166672; called by muse, mutect2
- MAD1L1 | c.1506G>T p.R502S | Missense Mutation (SNP) | VAF 79/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1229006689; called by muse, mutect2, varscan2
- MYO7B | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs563118213, COSV67345444; called by muse, mutect2
- NTRK3 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 115/452 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62299082; called by muse, mutect2, varscan2
- OBSCN | c.21523C>T p.R7175C | Missense Mutation (SNP) | VAF 122/630 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs993631362; called by muse, mutect2, varscan2
- OR2J3 | c.413T>A p.L138H | Missense Mutation (SNP) | VAF 156/1005 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65848746; called by muse, mutect2, varscan2
- RBBP8NL | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 115/413 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV53348242; called by muse, mutect2, varscan2
- YDJC | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 123/519 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs191054568; called by muse, mutect2, varscan2
- ACTN2 | c.1124G>T p.W375L | Missense Mutation (SNP) | VAF 68/377 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD6 | c.1670C>A p.P557Q (on ENST00000339746 / NM_001242809.2; = p.P552Q on NM_014942.4) | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- APEX2 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 134/422 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CXADR | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- HNRNPH2 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 148/594 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HPSE | c.1582del p.S528Hfs*6 | Frame Shift Del (DEL) | VAF 76/318 reads (24%) | called by mutect2, pindel, varscan2
- IGSF5 | c.197G>T p.W66L | Missense Mutation (SNP) | VAF 125/457 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IZUMO1 | c.209A>T p.N70I | Missense Mutation (SNP) | VAF 80/384 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IZUMO1 | c.208A>T p.N70Y | Missense Mutation (SNP) | VAF 82/386 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- KRTAP1-3 | c.46A>C p.T16P | Missense Mutation (SNP) | VAF 91/660 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- KRTAP10-10 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 106/500 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2
- LRFN2 | c.1718G>T p.S573I | Missense Mutation (SNP) | VAF 106/684 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LYST | c.5531A>G p.Y1844C | Missense Mutation (SNP) | VAF 73/415 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYO18B | c.3958C>A p.L1320I | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- NPM1 | c.381T>G p.D127E | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- NSA2 | c.148T>G p.Y50D | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PLA2R1 | c.3849A>C p.E1283D | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- RIMKLB | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.012); called by muse, mutect2
- SAMHD1 | c.880A>G p.K294E | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ST14 | c.2201A>G p.D734G | Missense Mutation (SNP) | VAF 126/363 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TRGV9 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIP12 | c.5435C>T p.P1812L | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TTLL12 | c.1267C>A p.L423M | Missense Mutation (SNP) | VAF 99/410 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- UPF1 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 99/304 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- WDR87 | c.4570G>C p.V1524L | Missense Mutation (SNP) | VAF 92/380 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AP000311.1 | c.249G>A p.V83= | Silent (SNP) | VAF 91/381 reads (24%) | catalogued as rs1264667681, COSV99285578; called by muse, mutect2, varscan2
- BNC1 | c.2583C>G p.T861= | Silent (SNP) | VAF 112/486 reads (23%) | called by muse, mutect2, varscan2
- DCBLD1 | c.846A>G p.Q282= | Silent (SNP) | VAF 78/318 reads (25%) | called by muse, mutect2, varscan2
- KLK5 | c.864C>A p.T288= | Silent (SNP) | VAF 85/297 reads (29%) | catalogued as rs532213513; called by muse, mutect2, varscan2
- SDK2 | c.1551C>T p.C517= | Silent (SNP) | VAF 34/554 reads (6%) | catalogued as rs776557649, COSV101166632; called by muse, mutect2
- SIGLEC8 | c.102G>T p.L34= | Silent (SNP) | VAF 90/388 reads (23%) | catalogued as COSV58473377; called by muse, varscan2
- SYNE1 | c.1398C>A p.I466= (on ENST00000367255 / NM_182961.4; = p.I473= on NM_033071.3) | Silent (SNP) | VAF 75/486 reads (15%) | called by muse, mutect2, varscan2
- VSIG10L | c.1944G>T p.L648= | Silent (SNP) | VAF 106/466 reads (23%) | called by muse, mutect2, varscan2
- WNT5A | c.1113G>A p.T371= | Silent (SNP) | VAF 58/215 reads (27%) | catalogued as rs751084010, COSV52836117; called by muse, mutect2, varscan2
- XKR6 | c.861C>A p.V287= | Silent (SNP) | VAF 90/361 reads (25%) | called by muse, mutect2, varscan2
- ZFHX3 | c.2346G>A p.A782= | Silent (SNP) | VAF 154/519 reads (30%) | catalogued as rs755319484, COSV51722986; called by muse, mutect2, varscan2
